Surgical pathology report (de-identified scan), TCGA case TCGA-N5-A4R8, project TCGA-UCS (Uterine Carcinosarcoma), tissue source site MSKCC, specimen TCGA-N5-A4R8-01A (Primary Tumor).

[page 1 of 2]
ICD-O-3
Carcinoma - Mixed Mullerian
Tumor 8950/3
Site: GSCF Uterus, NOS
C55.9
path Endometrium C54.1

Specimens Submitted:

- 1: SP: Uterus, cervix, bilateral tubes and ovaries
- 2: SP: Right para-aortic lymph nodes
- 3: SP: Left para-aortic lymph nodes
- 4: SP: Left common iliac lymph nodes
- 5: SP: Left external iliac lymph nodes
- 6: SP: Left internal iliac lymph nodes
- 7: SP: Left obturator lymph nodes
- 8: SP: Right external iliac lymph nodes
- 9: SP: Right internal iliac lymph nodes
- 10: SP: Right obturator lymph nodes
- 11: SP: Right common lymph nodes

DIAGNOSIS:

- 1) UTERUS, CERVIX, FALLOPIAN TUBES AND OVARIES; HYSTERECTOMY WITH BILATERAL SALPINGO-OOPHORECTOMY:
- MALIGNANT MIXED MULLERIAN TUMOR OF ENDOMETRIUM, WITH HETEROLOGOUS ELEMENTS (RHABDOMYOBlastic AND CARTILAGINOUS COMPONENTS).
- THE TUMOR INVADES TO $\leq$ HALF OF MYOMETRIUM.
- THE MAXIMAL THICKNESS OF MYOMETRIAL INVASION IS 3.5 MM.
- THE THICKNESS OF THE MYOMETRIUM IN THE AREA OF MAXIMAL TUMOR INVASION IS 23 MM.
- NO ENDOCERVICAL INVASION IS IDENTIFIED.
- NO VASCULAR INVASION IS IDENTIFIED.
- THE ENDOMETRIUM SHOWS THE FOLLOWING ABNORMALITY: ATROPHY.
- THE MYOMETRIUM SHOWS THE FOLLOWING ABNORMALITIES: LEIOMYOMAS.
- THE LEFT FALLOPIAN TUBE SHOWS PARATUBAL CYSTS.
- ALL OTHER ADNEXAE ARE UNREMARKABLE.
- 2) LYMPH NODES, RIGHT PARA-AORTIC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).
- 3) LYMPH NODES, LEFT PARA-AORTIC; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).
- 4) LYMPH NODES, LEFT COMMON ILIAC; EXCISION:

** Continued on next page **

PATH
REPORT

[page 2 of 2]
[REDACTED]

- SIX BENIGN LYMPH NODES (0/6).

5) LYMPH NODES, LEFT EXTERNAL ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

6) LYMPH NODES, LEFT INTERNAL ILIAC; EXCISION:
- THREE BENIGN LYMPH NODES (0/3).

7) LYMPH NODES, LEFT OBTURATOR; EXCISION:
- FIVE BENIGN LYMPH NODES (0/5).

8) LYMPH NODES, RIGHT EXTERNAL ILIAC; EXCISION:
- ONE BENIGN LYMPH NODE (0/1).

9) LYMPH NODES, RIGHT INTERNAL ILIAC; EXCISION:
- BENIGN FIBROADIPOSE TISSUE.
- NO LYMPH NODES PRESENT.

10) LYMPH NODES, RIGHT OBTURATOR; EXCISION:
- SEVEN BENIGN LYMPH NODES (0/7).

11) LYMPH NODES, RIGHT COMMON ILIAC; EXCISION:
- TWO BENIGN LYMPH NODES (0/2).

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

[REDACTED]
*** Report Electronically Signed Out *** [REDACTED]

12/31/12

Source: NCI Genomic Data Commons file b0332048-53e5-43da-a935-970b6750a352 (TCGA-N5-A4R8.AF57F4A5-49C7-4896-AB32-EF6E72DAA70F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).